MMRF case MMRF_1155 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8bb96689-fe0a-45b5-af07-3a6c30480927

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.1 years (23,036 days); ISS stage: II; Days to last known disease status: 1,708 days (4.7 years); Days to last follow up: 1,708 days (4.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 67 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 596 days (1.6 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 105 days.
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,473 days (4.0 years); Days to treatment end: 1,586 days (4.3 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,591 days (4.4 years); Days to treatment end: 1,591 days (4.4 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,593 days (4.4 years); Days to treatment end: 1,593 days (4.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 1): M Protein 7.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Immunoglobulin G 95.5 g/L; Immunoglobulin A 0.434 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 5.2 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 5.1 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 136 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 28 g/L; Total Protein 15.3 g/dL; Glucose 6.93 mmol/L.
- Day 84 (ECOG 1): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 30.6 g/L; Immunoglobulin A 0.793 g/L; Immunoglobulin M 0.518 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 7.7 g/dL; Glucose 6.16 mmol/L.
- Day 175 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.64 mg/dL; Immunoglobulin G 18.4 g/L; Immunoglobulin A 2.26 g/L; Immunoglobulin M 3.8 g/L; Beta 2 Microglobulin 4.4 µg/mL; Lactate Dehydrogenase 4.15 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 343 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 31 g/L; Total Protein 7.5 g/dL; Glucose 5.94 mmol/L.
- Day 266: Hemoglobin 7.56 mmol/L; Leukocytes 5 ×10⁹/L; Platelets 213 ×10⁹/L.
- Day 329: Hemoglobin 7.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 234 ×10⁹/L.
- Day 448: Hemoglobin 8.74 mmol/L; Leukocytes 5.1 ×10⁹/L.
- Day 543 (ECOG 4): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.58 mg/dL; Beta 2 Microglobulin 2.4 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 4.4 mmol/L.
- Day 606 (ECOG 4): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Beta 2 Microglobulin 2.1 µg/mL; Hemoglobin 8.68 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 5.01 mmol/L.
- Day 718 (ECOG 4): M Protein 0.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Beta 2 Microglobulin 2.49 µg/mL; Hemoglobin 9.11 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 2.95 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 6.05 mmol/L.
- Day 788 (ECOG 4): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Beta 2 Microglobulin 2.48 µg/mL; Hemoglobin 8.68 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.45 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 5.01 mmol/L.
- Day 875 (ECOG 1): Hemoglobin 9.18 mmol/L; Leukocytes 8.2 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Glucose 5.01 mmol/L.
- Day 1,050 (ECOG 1): M Protein 0.66 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.91 mg/dL; Beta 2 Microglobulin 2.35 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 7.48 mmol/L.
- Day 1,141: Hemoglobin 8.18 mmol/L; Leukocytes 5 ×10⁹/L; Platelets 192 ×10⁹/L.
- Day 1,253: Hemoglobin 8.06 mmol/L; Leukocytes 5.8 ×10⁹/L; Platelets 196 ×10⁹/L.
- Day 1,313: M Protein 2.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Hemoglobin 8.12 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.36 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.05 mmol/L; Albumin 32 g/L; Total Protein 8.8 g/dL; Glucose 5.34 mmol/L.
- Day 1,404: M Protein 5.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Hemoglobin 7.56 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.75 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.08 mmol/L; Albumin 29 g/L; Total Protein 11.6 g/dL; Glucose 4.68 mmol/L.
- Day 1,530 (ECOG 1): M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 37.6 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 29 g/L; Total Protein 8.6 g/dL; Glucose 4.24 mmol/L.
- Day 1,635 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 5.25 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 13.3 ×10⁹/L; Absolute Neutrophil 11.6 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 229 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 6.9 g/dL; Glucose 9.08 mmol/L.
- Day 1,708 (ECOG 2): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 1.28 g/L; Lactate Dehydrogenase 4.48 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 5.94 mmol/L.

Other clinical attributes
- Day -11: Weight: 89 kg; Height: 171 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (3 samples)
- Sample MMRF_1155_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_1155_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
- Sample MMRF_1155_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 1,530 days (4.2 years).
